Somatic mutation profile of tumor specimen TCGA-06-5416-01A (aliquot TCGA-06-5416-01A-01D-1486-08) from TCGA case TCGA-06-5416, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.4 years (8,533 days).
Specimen TCGA-06-5416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 005aa6b2-3697-44da-9e3b-9a7aec76825b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5416-10A (Blood Derived Normal), aliquot TCGA-06-5416-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99c228a0-02df-46f2-a095-68e72e53b159

The open-access MAF lists 15,218 somatic variants for this specimen: 11,274 protein-altering or splice-affecting, 3,596 silent, 348 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10,005, Silent 3,596, Nonsense Mutation 953, Splice Site 175, Intron 150, RNA 85, Splice Region 83, 3'UTR 43, Frame Shift Ins 42, 5'UTR 28, 3'Flank 23, 5'Flank 18.

Variants (750 of 15,218; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs62645952, CM022997; ClinVar: pathogenic; called by muse, varscan2
- ABCD1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517954, CM003649, CM005540, CM950035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADM | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 145/338 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs398123072, CM920003, COSV63720064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 79/193 reads (41%) | catalogued as rs747975445; ClinVar: pathogenic; called by muse, varscan2
- ARMC9 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs1114167449; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARSB | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 96/416 reads (23%) | catalogued as rs891298440, CM003996, COSV53728737; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.990A>C p.E330D | Missense Mutation (SNP) | VAF 72/233 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55467922; called by muse, mutect2, varscan2
- BCL2 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 89/185 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.25); PolyPhen possibly damaging (0.786); catalogued as COSV61371678, COSV61372495, COSV61374245; called by muse, mutect2, varscan2
- CA5A | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 114/297 reads (38%) | catalogued as rs767402215, COSV59239468; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CBL | c.1096-1G>T p.X366_splice | Splice Site (SNP) | VAF 26/80 reads (33%) | catalogued as rs397517076, CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLDN14 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74315438, CM051892, COSV59777269; ClinVar: likely pathogenic; called by muse, varscan2
- CSTA | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 66/163 reads (40%) | catalogued as rs149474339, CM156004; ClinVar: pathogenic; called by muse, varscan2
- DCC | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 70/347 reads (20%) | catalogued as rs1085307773, COSV59101172; ClinVar: likely pathogenic; called by muse, varscan2
- DNAH5 | c.5992G>A p.G1998R | Missense Mutation (SNP) | VAF 114/253 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298790222; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNMT3B | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 80/420 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1438362757, COSV52419146; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EBF2 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 140/322 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV68776268, COSV68778111; called by muse, varscan2
- ERCC4 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147105770, CM101828; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.7828G>A p.E2610K | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs111984349, CM972822; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FBN1 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs112911555, CM091207; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- G6PD | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs137852334, CM920285; ClinVar: other / pathogenic; called by muse, mutect2, varscan2
- GAA | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs201896815, CM020003; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GABRG2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 153/304 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs121909673, CM011783; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HNF4A | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1555813319, CM111488, COSV57385421; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- IRAK3 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 164/365 reads (45%) | catalogued as rs367600113, COSV104370772; ClinVar: likely pathogenic; called by muse, varscan2
- IRF6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121434226, CM044898, HM040054, COSV65419014, COSV65419483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs193922365, CM043015, CM097188; ClinVar: likely pathogenic / not provided; called by mutect2, varscan2
- KCNQ3 | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs754896169, COSV101196201; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KLHL3 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs199469636, CM120743; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 55/129 reads (43%) | catalogued as rs886039402, CM022620, COSV60667006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as rs1303773212, COSV70342690; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- LRIT3 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 26/205 reads (13%) | catalogued as rs397509378, CM130261, COSV59987232; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAGT1 | c.895C>T p.R299* (on ENST00000618282 / NM_001367916.1; = p.R331* on NM_032121.5) | Nonsense Mutation (SNP) | VAF 57/198 reads (29%) | catalogued as rs1569547876, COSV63234238; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MMUT | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 37/159 reads (23%) | catalogued as rs761525156, CM050686, COSV51279742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 164/402 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs574132670, CM155651, COSV64701534, COSV64701602; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- MTM1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as rs781933660, CM970997, COSV100080340, COSV60336339; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5101C>T p.R1701* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as rs111033182, CM060388; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NF1 | c.5269-1G>A p.X1757_splice (on ENST00000358273 / NM_001042492.3; = p.X1736_splice on NM_000267.3) | Splice Site (SNP) | VAF 20/108 reads (19%) | catalogued as rs876660141, CS1411400, CS153442, COSV62192457; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NOTCH2 | c.7198C>T p.R2400* | Nonsense Mutation (SNP) | VAF 43/234 reads (18%) | hotspot (GDC flag); catalogued as rs1325403451, CM112315, COSV56682519; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 132/288 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 94/309 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- POGZ | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 70/197 reads (36%) | catalogued as rs1557901051, COSV55035225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 137/361 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 37/184 reads (20%) | hotspot (GDC flag); catalogued as rs759850701, COSV59954557; called by muse, mutect2, varscan2
- PSMD12 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 51/200 reads (26%) | catalogued as rs895130488, COSV62066198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 97/532 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- RICTOR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 153/358 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776074870, COSV57119127; called by muse, mutect2, varscan2
- ROR2 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529829552; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- RP2 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 95/361 reads (26%) | catalogued as rs104894927, CM991106, COSV54463407; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RS1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs61752159, CM981753, COSV101183688; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 60/115 reads (52%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, varscan2
- RYR1 | c.14209C>T p.R4737W | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs193922867, CM023979; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SC5D | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 64/160 reads (40%) | catalogued as rs1313359281, COSV50612637; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs1480085793, CM093256; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SERPINC1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs121909563, CM900039; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SLC2A2 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 49/237 reads (21%) | catalogued as rs121909742, CM971383, COSV58585414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC4A1 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912755, CM951169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SON | c.5473C>T p.R1825* | Nonsense Mutation (SNP) | VAF 44/194 reads (23%) | catalogued as rs1569058837; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1039C>T p.R347* (on ENST00000273980 / NM_001163436.4; = p.R284* on NM_033115.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/180 reads (24%) | catalogued as rs762552974, COSV56760040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 237/598 reads (40%) | catalogued as rs869025531, CM1210056, COSV65109013, COSV65110174; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TGFB2 | c.821dup p.N274Kfs*19 | Frame Shift Ins (INS) | VAF 75/195 reads (38%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TNNC1 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs730881058, COSV51767003; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 110/114 reads (96%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.69906T>G p.Y23302* (on ENST00000591111; = p.Y15878* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 93/272 reads (34%) | catalogued as rs1553604563; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TYR | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747995722, CM085760, HM050006, COSV54480257; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UBE3A | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as rs886043612, COSV51664919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UGT1A1 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs72551353, CM941356; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 182/325 reads (56%) | catalogued as rs137852981, CM013801, COSV57956692; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZFYVE26 | c.4132C>T p.R1378* | Nonsense Mutation (SNP) | VAF 32/166 reads (19%) | catalogued as rs774809466, COSV61327754; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs576930283, COSV100588341, COSV100588832; called by muse, mutect2, varscan2
- A2M | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59382738; called by muse, mutect2, varscan2
- A2ML1 | c.2590+2T>C p.X864_splice | Splice Site (SNP) | VAF 156/321 reads (49%) | catalogued as rs1372950019; called by muse, mutect2, varscan2
- A4GALT | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs199938085; called by muse, varscan2
- A4GNT | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs775713265, COSV52628454; called by muse, mutect2, varscan2
- AARS1 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1033300766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AARS2 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756662327, COSV55116404; called by muse, mutect2, varscan2
- AATF | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 135/343 reads (39%) | catalogued as rs759338868; called by muse, mutect2, varscan2
- ABAT | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs766849835, COSV99191006; called by muse, mutect2, varscan2
- ABCA1 | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV66065126; called by muse, varscan2
- ABCA1 | c.4002G>A p.W1334* | Nonsense Mutation (SNP) | VAF 48/213 reads (23%) | catalogued as rs757389241; called by muse, mutect2, varscan2
- ABCA1 | c.3480G>T p.Q1160H | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as COSV101037242; called by muse, mutect2, varscan2
- ABCA12 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV55964861; called by muse, mutect2, varscan2
- ABCA12 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 89/142 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762065937, CM130513, COSV55948982; called by muse, mutect2, varscan2
- ABCA13 | c.7048G>T p.E2350* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV71284578, COSV71286769; called by muse, mutect2, varscan2
- ABCA2 | c.5215G>T p.A1739S (on ENST00000614293; = p.A1709S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs756252284; called by muse, mutect2, varscan2
- ABCA2 | c.3102G>T p.K1034N (on ENST00000614293; = p.K1004N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs747908059; called by muse, mutect2, varscan2
- ABCA4 | c.5018+1G>A p.X1673_splice | Splice Site (SNP) | VAF 167/374 reads (45%) | catalogued as CS1411984; called by muse, mutect2, varscan2
- ABCA4 | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs772463435; called by muse, varscan2
- ABCA5 | c.4645G>T p.E1549* | Nonsense Mutation (SNP) | VAF 51/215 reads (24%) | catalogued as COSV67016201; called by muse, mutect2, varscan2
- ABCA7 | c.2271C>T p.G757= | Splice Region (SNP) | VAF 21/38 reads (55%) | catalogued as COSV99565721; called by muse, mutect2, varscan2
- ABCA7 | c.3367C>T p.R1123W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs569436931; called by muse, varscan2
- ABCA9 | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs765755245, COSV60621338; called by muse, varscan2
- ABCB10 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752270393; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCB5 | c.3460G>T p.A1154S (on ENST00000404938 / NM_001163941.2; = p.A709S on NM_178559.6) | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV51716288; called by muse, mutect2, varscan2
- ABCB8 | c.1405C>T p.R469C (on ENST00000297504 / NM_001282291.2; = p.R452C on NM_007188.5) | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as rs1242097667; called by muse, varscan2
- ABCC1 | c.3969C>T p.V1323= | Splice Region (SNP) | VAF 62/316 reads (20%) | catalogued as rs759266398, COSV60695684; called by muse, mutect2, varscan2
- ABCC11 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs199502121, COSV62326454; called by muse, mutect2, varscan2
- ABCC12 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs138774498, COSV104409772; called by muse, mutect2, varscan2
- ABCC3 | c.3160C>T p.R1054C | Missense Mutation (SNP) | VAF 181/429 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs141068276, COSV99559517; called by muse, mutect2, varscan2
- ABCC3 | c.4052G>A p.G1351D | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs767230399; called by muse, mutect2, varscan2
- ABCC5 | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 101/182 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV55593835; called by muse, varscan2
- ABCC5 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1309542209, COSV55586736; called by muse, varscan2
- ABCC6 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52741167; called by muse, varscan2
- ABCC8 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs950691063, COSV56852297; called by muse, mutect2, varscan2
- ABCC9 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs148752791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs782458499, COSV99497292; called by muse, mutect2, varscan2
- ABCD3 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 53/253 reads (21%) | catalogued as rs767729300; called by muse, mutect2, varscan2
- ABCD3 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 32/152 reads (21%) | catalogued as rs373698570; called by muse, mutect2, varscan2
- ABCD3 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 55/291 reads (19%) | catalogued as COSV64642479; called by muse, mutect2, varscan2
- ABCE1 | c.1139A>T p.E380V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56847263; called by muse, mutect2, varscan2
- ABCF1 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 40/143 reads (28%) | catalogued as rs1561786344, COSV58228142; called by muse, varscan2
- ABCG1 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.103); catalogued as COSV59202607; called by muse, mutect2, varscan2
- ABCG2 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs774014561; called by muse, mutect2, varscan2
- ABCG8 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 94/167 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as rs759654526; called by muse, varscan2
- ABHD16A | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as rs745835378, COSV65452176; called by muse, varscan2
- ABL1 | c.2972C>T p.A991V | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs148337803; called by muse, mutect2, varscan2
- ABL1 | c.3280C>A p.L1094I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59326156; called by muse, mutect2, varscan2
- ABO | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.109); catalogued as rs781806838; called by muse, mutect2, varscan2
- ABRA | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 148/523 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as rs756024441; called by muse, mutect2, varscan2
- ABTB2 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs138784665; called by muse, mutect2, varscan2
- AC006059.2 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as rs760529333; called by muse, varscan2
- AC006059.2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs901644142; called by muse, varscan2
- AC011462.1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 95/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868148933; called by muse, mutect2, varscan2
- AC013477.1 | c.2614G>A p.A872T | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs558905999, COSV53654513, COSV53655900; called by muse, mutect2, varscan2
- AC093246.1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV51125905; called by muse, mutect2, varscan2
- AC126283.2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs777190530, CM1311004, COSV101144288; called by muse, varscan2
- AC132217.2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs376704926; called by muse, mutect2, varscan2
- AC245748.1 | c.16-1G>T p.X6_splice | Splice Site (SNP) | VAF 51/316 reads (16%) | catalogued as COSV100495441; called by muse, mutect2, varscan2
- ACAA1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 149/270 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151138541; called by muse, mutect2, varscan2
- ACACB | c.4062C>A p.F1354L | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV58138670; called by muse, varscan2
- ACACB | c.4821C>T p.I1607= | Splice Region (SNP) | VAF 73/168 reads (43%) | catalogued as rs776234149, COSV58128696; called by muse, mutect2, varscan2
- ACADS | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs756016434, COSV54368224; called by muse, mutect2, varscan2
- ACAN | c.6346G>A p.A2116T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.184); catalogued as rs747312001, COSV61363835; called by muse, mutect2, varscan2
- ACAP1 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1365779852, COSV50134311; called by muse, mutect2, varscan2
- ACCS | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV99772887; called by muse, mutect2, varscan2
- ACCS | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs140784310; called by muse, mutect2, varscan2
- ACCS | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV55457846; called by muse, mutect2, varscan2
- ACE | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs13306085; called by muse, mutect2, varscan2
- ACER3 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781838638; called by muse, mutect2, varscan2
- ACIN1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs1289587887; called by muse, mutect2, varscan2
- ACIN1 | c.610+1G>A p.X204_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as rs1266963107; called by muse, mutect2, varscan2
- ACLY | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs868928688; called by muse, mutect2, varscan2
- ACO1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs201900147; called by muse, mutect2, varscan2
- ACOT12 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766442464; called by muse, mutect2, varscan2
- ACOT8 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748013618, COSV54171573; called by muse, mutect2, varscan2
- ACOXL | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs762071917, COSV61323479; called by muse, varscan2
- ACOXL | c.1063T>C p.Y355H | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1347626470; called by muse, mutect2, varscan2
- ACP4 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 141/324 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs776124599; called by muse, varscan2
- ACP5 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs149133430; called by muse, mutect2, varscan2
- ACSL3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs531866665, COSV62482434; called by muse, mutect2, varscan2
- ACSL4 | c.1355G>A p.R452Q (on ENST00000340800 / NM_022977.2; = p.R411Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/267 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as rs776295981; called by muse, mutect2, varscan2
- ACSL5 | c.364C>A p.L122I (on ENST00000354273; = p.L178I on NM_016234.3) | Missense Mutation (SNP) | VAF 156/673 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61131365; called by muse, mutect2, varscan2
- ACSM1 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 238/535 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs752963497; called by muse, mutect2, varscan2
- ACSM2A | c.382C>T p.R128* (on ENST00000219054; = p.R49* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | catalogued as rs748565082, COSV54589440; called by muse, mutect2, varscan2
- ACSM4 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV68067891, COSV68069762; called by muse, mutect2, varscan2
- ACSS2 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs757812388, COSV53628675; called by muse, mutect2, varscan2
- ACSS3 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760939820, COSV54098981; called by muse, mutect2, varscan2
- ACSS3 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54089963; called by muse, mutect2, varscan2
- ACTL7B | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs758754533; called by muse, mutect2, varscan2
- ACTL8 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100958528; called by muse, mutect2, varscan2
- ACTL8 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1352379563; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR5 | c.1343G>T p.R448I | Missense Mutation (SNP) | VAF 179/265 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54762423; called by muse, mutect2, varscan2
- ACVR1 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314502834; called by muse, mutect2, varscan2
- ACVRL1 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.129); catalogued as rs1156690415; called by muse, mutect2, varscan2
- ADAM17 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV60397996, COSV60398180; called by muse, varscan2
- ADAM23 | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs982795571, COSV52220908; called by muse, mutect2, varscan2
- ADAM29 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100822266; called by muse, mutect2
- ADAM8 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759947382; called by muse, mutect2, varscan2
- ADAMTS13 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as rs1554791538; called by muse, mutect2
- ADAMTS13 | c.3368G>A p.R1123H | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs782311861, CM1313286, COSV52470461; called by muse, mutect2, varscan2
- ADAMTS15 | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.784); catalogued as rs1205239153, COSV54507874; called by muse, mutect2, varscan2
- ADAMTS15 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1440774847; called by muse, mutect2, varscan2
- ADAMTS16 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs375714169; called by muse, mutect2, varscan2
- ADAMTS16 | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56984007, COSV57000397; called by muse, mutect2, varscan2
- ADAMTS18 | c.3324G>T p.E1108D | Missense Mutation (SNP) | VAF 150/361 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV51400466; called by muse, mutect2, varscan2
- ADAMTS18 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759290262, COSV51407885; called by muse, varscan2
- ADAMTS18 | c.1145G>T p.R382I | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51402028; called by muse, mutect2, varscan2
- ADAMTS2 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1198528313, COSV52398758; called by muse, mutect2, varscan2
- ADAMTS2 | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778993977; called by muse, mutect2, varscan2
- ADAMTS2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as rs749842975, COSV99206298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV67132785; called by muse, mutect2, varscan2
- ADAMTS20 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as rs749434282, COSV67129549; called by muse, mutect2, varscan2
- ADAMTS7 | c.4774C>T p.R1592C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751363176, COSV66309810; called by muse, mutect2, varscan2
- ADAMTS9 | c.5033C>T p.S1678L | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138753923; called by muse, varscan2
- ADAMTS9 | c.4628C>T p.P1543L | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs775114165; called by muse, mutect2, varscan2
- ADAMTS9 | c.2213G>A p.R738Q | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs567830374, COSV55781997; called by muse, mutect2, varscan2
- ADAMTS9 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs370310120; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3277C>T p.R1093C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs1311802567, COSV65888655; called by muse, mutect2, varscan2
- ADAMTSL3 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717444; called by muse, mutect2, varscan2
- ADAT1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755063906; called by muse, mutect2, varscan2
- ADCK1 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs752581267, COSV53079235; called by muse, mutect2, varscan2
- ADCK5 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.059); catalogued as rs1554860284; called by muse, mutect2, varscan2
- ADCY1 | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52032703; called by muse, mutect2, varscan2
- ADCY10 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs895969024; called by muse, mutect2, varscan2
- ADCY2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 146/299 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs372373069; called by muse, mutect2, varscan2
- ADCY3 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 143/267 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777689844, COSV53171677; called by muse, varscan2
- ADCY8 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 174/366 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475267602, COSV53905124; called by muse, varscan2
- ADCY9 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 103/458 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs964742894, COSV53573698; called by muse, mutect2, varscan2
- ADD3 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV53325707; called by muse, mutect2, varscan2
- ADGRA3 | c.3577G>A p.D1193N | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1442522622; called by muse, mutect2, varscan2
- ADGRA3 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 155/510 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs1168753717; called by muse, mutect2, varscan2
- ADGRE1 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs972096447, COSV51678090; called by muse, mutect2, varscan2
- ADGRE1 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 79/131 reads (60%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); catalogued as rs372416153; called by muse, varscan2
- ADGRF3 | c.1351G>A p.A451T (on ENST00000311519 / NM_001145168.1; = p.A252T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.602); catalogued as rs1398106177; called by muse, mutect2, varscan2
- ADGRF3 | c.388C>A p.L130M (on ENST00000311519 / NM_001145168.1; = p.L71M on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV100275331; called by muse, mutect2, varscan2
- ADGRF5 | c.3428C>T p.S1143L | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1327922158, COSV51939297; called by muse, mutect2, varscan2
- ADGRG6 | c.3255C>A p.F1085L | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.34); catalogued as COSV99747042; called by muse, mutect2, varscan2
- ADGRG7 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 77/424 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as rs372225636; called by muse, mutect2, varscan2
- ADGRG7 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs541591554; called by muse, varscan2
- ADGRL2 | c.3095A>G p.N1032S (on ENST00000370717 / NM_001366005.1; = p.N1019S on NM_012302.4) | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.369); catalogued as COSV99588792; called by muse, mutect2, varscan2
- ADGRL2 | c.3365C>T p.T1122I (on ENST00000370717 / NM_001366005.1; = p.T1109I on NM_012302.4) | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1200046628; called by muse, varscan2
- ADGRL3 | c.2413C>T p.R805* (on ENST00000506720 / NM_001322402.2; = p.R737* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV101547294; called by muse, mutect2, varscan2
- ADGRV1 | c.2320G>A p.G774R | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67991548; called by muse, mutect2, varscan2
- ADGRV1 | c.16592C>A p.S5531Y | Missense Mutation (SNP) | VAF 121/527 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.424); catalogued as COSV101316414; called by muse, mutect2, varscan2
- ADGRV1 | c.17896G>A p.A5966T | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200380522, COSV67995119; called by muse, varscan2
- ADGRV1 | c.18331C>A p.L6111I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101315597; called by muse, mutect2, varscan2
- ADH1A | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 78/813 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs781090973, COSV52924876; called by muse, mutect2
- ADH1B | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV59296534; called by muse, mutect2, varscan2
- ADH1C | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs750873906, COSV72463652; called by muse, mutect2
- ADH6 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV52957868; called by muse, mutect2, varscan2
- ADNP2 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs766821105, COSV51537235; called by muse, mutect2, varscan2
- ADORA1 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 120/238 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as COSV58809844; called by muse, mutect2, varscan2
- ADORA1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.747); catalogued as rs778641521, COSV55142136, COSV99704669; called by muse, varscan2
- ADRA1B | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs1402567797; called by muse, mutect2, varscan2
- ADRA2C | c.1382G>T p.R461M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.316); catalogued as COSV57468211; called by muse, mutect2, varscan2
- ADRB2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 254/500 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60005441; called by muse, mutect2, varscan2
- AFDN | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as rs775055966; called by muse, mutect2, varscan2
- AFF2 | c.3195T>A p.F1065L | Missense Mutation (SNP) | VAF 202/352 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99665866; called by muse, mutect2, varscan2
- AFMID | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 103/463 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs779472218, COSV59975517; called by muse, mutect2, varscan2
- AFMID | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs751911915; called by muse, mutect2, varscan2
- AFP | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs781592078, COSV56927383; called by muse, mutect2, varscan2
- AFP | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56924389; called by muse, mutect2, varscan2
- AGAP3 | c.1835G>A p.R612H (on ENST00000622464; = p.R648H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs779165451; called by muse, mutect2, varscan2
- AGBL1 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as COSV69800126; called by muse, mutect2, varscan2
- AGMO | c.832T>G p.L278V | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs1321686491; called by muse, mutect2, varscan2
- AGO1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs748561732, COSV64594648; called by muse, mutect2, varscan2
- AGO1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV64594678; called by muse, varscan2
- AGO1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1385468503, COSV64595638; called by muse, varscan2
- AGPAT4 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs200080197; called by muse, mutect2, varscan2
- AGRN | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs763762094, COSV65071772; called by muse, mutect2, varscan2
- AGT | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.648); catalogued as rs1260609293; called by muse, mutect2, varscan2
- AGTPBP1 | c.2620C>T p.R874W (on ENST00000357081 / NM_001330701.2; = p.R834W on NM_015239.2) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1418982979, COSV61270623; called by muse, mutect2, varscan2
- AGTPBP1 | c.2039A>C p.E680A (on ENST00000357081 / NM_001330701.2; = p.E640A on NM_015239.2) | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV104396815; called by muse, mutect2, varscan2
- AHCTF1 | c.6025C>T p.R2009C (on ENST00000366508; = p.R1983C on NM_015446.5) | Missense Mutation (SNP) | VAF 154/364 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs760993765; called by muse, mutect2, varscan2
- AHCTF1 | c.626A>G p.D209G (on ENST00000366508; = p.D183G on NM_015446.5) | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV58254825; called by muse, mutect2, varscan2
- AHDC1 | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs923632705, COSV55940700; called by muse, mutect2, varscan2
- AHI1 | c.3191C>T p.A1064V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769705227, COSV55637817; called by muse, mutect2, varscan2
- AHI1 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55632351; called by muse, mutect2, varscan2
- AHNAK | c.4712G>T p.S1571I | Missense Mutation (SNP) | VAF 143/349 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99947405; called by muse, mutect2, varscan2
- AHNAK | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV57229985; called by muse, mutect2, varscan2
- AHNAK2 | c.13112T>C p.V4371A | Missense Mutation (SNP) | VAF 127/172 reads (74%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as rs1159932106, COSV100317856; called by muse, mutect2, varscan2
- AHNAK2 | c.9705G>T p.K3235N | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60911952; called by muse, mutect2, varscan2
- AHNAK2 | c.9210G>T p.K3070N | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60911960; called by muse, mutect2, varscan2
- AHNAK2 | c.6863T>C p.V2288A | Missense Mutation (SNP) | VAF 229/289 reads (79%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.875); catalogued as COSV60920986, COSV60927343; called by muse, mutect2, varscan2
- AHR | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs775338539; called by muse, mutect2, varscan2
- AHRR | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338722288; called by muse, varscan2
- AICDA | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.033); catalogued as rs772899277; called by muse, mutect2, varscan2
- AJAP1 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65450828; called by muse, mutect2, varscan2
- AK6 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs768063459, COSV66459208; called by muse, mutect2, varscan2
- AKAP12 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs199808949; called by muse, mutect2, varscan2
- AKAP13 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs769554632, COSV63464576; called by muse, mutect2, varscan2
- AKAP6 | c.6011C>A p.S2004* | Nonsense Mutation (SNP) | VAF 58/168 reads (35%) | catalogued as COSV99798010; called by muse, mutect2, varscan2
- AKAP7 | c.1037A>G p.N346S (on ENST00000431975 / NM_016377.4; = p.N79S on NM_004842.4) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs540604847; called by muse, mutect2, varscan2
- AKAP9 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.264); catalogued as COSV62350086; called by muse, mutect2, varscan2
- AKAP9 | c.4247T>G p.F1416C | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV62348540; called by muse, mutect2, varscan2
- AKIP1 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV55148416; called by muse, mutect2, varscan2
- AKR1C1 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs777883111; called by muse, mutect2, varscan2
- AKT3 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 105/227 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV55609365; called by muse, mutect2, varscan2
- AL136295.1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as rs575738905, COSV99841673; called by muse, mutect2, varscan2
- AL592490.1 | c.2822G>A p.R941Q | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as rs770540877, COSV69425962; called by muse, mutect2, varscan2
- AL592490.1 | c.1812G>T p.K604N | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.551); catalogued as COSV69427217; called by muse, varscan2
- AL592490.1 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV101308308, COSV69425245; called by muse, mutect2, varscan2
- ALAS1 | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV59627647; called by muse, mutect2, varscan2
- ALB | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs150388973, COSV55735680; called by muse, mutect2, varscan2
- ALDH1A2 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs374758581, COSV51089223; called by muse, mutect2, varscan2
- ALDH1L1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs9282692, COSV56418272; called by muse, mutect2, varscan2
- ALDH3B2 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs751103684; called by muse, varscan2
- ALDOA | c.586G>A p.G196R (on ENST00000642816 / NM_001243177.4; = p.G142R on NM_184041.5) | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386172871; called by muse, mutect2, varscan2
- ALDOB | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 80/120 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV66398127; called by muse, mutect2, varscan2
- ALDOC | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 154/378 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs1484302705; called by muse, mutect2, varscan2
- ALDOC | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 91/496 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs765845189, COSV52024310; called by muse, mutect2, varscan2
- ALDOC | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99256868; called by muse, mutect2, varscan2
- ALG10B | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 95/453 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58142349; called by muse, mutect2, varscan2
- ALG3 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373981212; called by muse, mutect2, varscan2
- ALG5 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT tolerated (0.7); PolyPhen benign (0.074); catalogued as rs781408999, COSV53504840; called by muse, mutect2, varscan2
- ALG8 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs201602294; called by muse, mutect2, varscan2
- ALG9 | c.1240G>A p.A414T (on ENST00000614444 / NM_001352418.1; = p.A421T on NM_024740.2) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs782251015; called by muse, varscan2
- ALKBH3 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs944525950; called by muse, mutect2, varscan2
- ALMS1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs776946280; called by muse, mutect2, varscan2
- ALMS1 | c.6783A>T p.E2261D | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52515783; called by muse, mutect2, varscan2
- ALOX15 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1170527133, COSV99541263; called by muse, mutect2, varscan2
- ALOX15 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs904067782; called by muse, mutect2, varscan2
- ALOXE3 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 194/472 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV59077655; called by muse, mutect2, varscan2
- ALPI | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55014372; called by muse, mutect2, varscan2
- ALPK1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779895727, COSV51583461; called by muse, mutect2, varscan2
- ALPK1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs377063660, COSV51584702; called by muse, mutect2, varscan2
- ALPK2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs763980190, COSV64489989; called by muse, varscan2
- ALS2 | c.4496G>A p.R1499H | Missense Mutation (SNP) | VAF 82/141 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs566436589; called by muse, mutect2, varscan2
- ALS2CL | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 143/262 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs117431144; called by muse, mutect2, varscan2
- ALX4 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 253/533 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs104894197, CM060200, COSV61324798; called by muse, mutect2, varscan2
- AMBRA1 | c.1151G>A p.R384H (on ENST00000458649 / NM_001367468.1; = p.R294H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.306); catalogued as rs958703115, COSV54054963; called by muse, mutect2, varscan2
- AMER1 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 74/308 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.299); catalogued as COSV57654238; called by muse, mutect2, varscan2
- AMIGO1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as rs779136835; called by muse, mutect2, varscan2
- AMOT | c.2975C>T p.A992V (on ENST00000371959 / NM_001113490.1; = p.A583V on NM_133265.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1453459963; called by muse, mutect2
- AMOTL2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs775980263, COSV51440144; called by muse, mutect2, varscan2
- AMPD1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746535692, COSV62415397, COSV62415673; called by muse, mutect2, varscan2
- AMPD3 | c.827G>A p.R276Q (on ENST00000396553 / NM_001025389.2; = p.R285Q on NM_000480.3) | Missense Mutation (SNP) | VAF 95/407 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1337058314, COSV67331970; called by muse, mutect2, varscan2
- AMPH | c.1541C>A p.T514N | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57743372; called by muse, mutect2
- AMT | c.259-1G>A p.X87_splice | Splice Site (SNP) | VAF 23/130 reads (18%) | catalogued as CS095325; called by muse, mutect2, varscan2
- ANAPC10 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs35257136; called by muse, mutect2, varscan2
- ANAPC5 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 114/624 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs782022766, COSV55841400; called by muse, mutect2, varscan2
- ANGEL1 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs760271205; called by muse, mutect2, varscan2
- ANGPTL5 | c.1130T>C p.M377T | Missense Mutation (SNP) | VAF 121/259 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57533160; called by muse, mutect2, varscan2
- ANK1 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs139513895, COSV55888615; called by muse, varscan2
- ANK1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 82/414 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746138074, COSV55886993; called by muse, mutect2, varscan2
- ANK2 | c.5606C>T p.A1869V | Missense Mutation (SNP) | VAF 169/398 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs983680857, COSV52162757; called by muse, mutect2, varscan2
- ANK2 | c.6205C>T p.R2069C | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs754572911, COSV52159875, COSV52189518; called by muse, mutect2, varscan2
- ANK3 | c.7672C>T p.R2558C | Missense Mutation (SNP) | VAF 79/380 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs375600068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.6121A>T p.I2041F | Missense Mutation (SNP) | VAF 159/354 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs797045236; called by muse, mutect2, varscan2
- ANK3 | c.3758C>T p.S1253L (on ENST00000280772 / NM_001320874.2; = p.S387L on NM_001149.3) | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745737001; called by muse, mutect2, varscan2
- ANK3 | c.2248C>A p.L750I | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV55054135; called by muse, mutect2, varscan2
- ANKEF1 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs145101692; called by muse, mutect2, varscan2
- ANKEF1 | c.2041C>A p.L681M | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs538974553; called by muse, mutect2, varscan2
- ANKEF1 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs765657099, COSV65692034, COSV65692218; called by muse, mutect2, varscan2
- ANKFY1 | c.1910G>A p.S637N | Missense Mutation (SNP) | VAF 89/222 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs200524118; called by muse, mutect2, varscan2
- ANKFY1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 138/316 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764800361, COSV58917315; called by muse, mutect2, varscan2
- ANKIB1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373205235; called by muse, mutect2, varscan2
- ANKLE1 | c.1910G>A p.R637H (on ENST00000394458; = p.R583H on NM_152363.6) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316256750, COSV101082280, COSV66732028; called by muse, varscan2
- ANKRD11 | c.4970C>T p.S1657L | Missense Mutation (SNP) | VAF 108/526 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749114664, COSV56362701; called by muse, mutect2, varscan2
- ANKRD11 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 117/235 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1385566000, COSV56359159; called by muse, mutect2, varscan2
- ANKRD13B | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1319329190; called by muse, mutect2, varscan2
- ANKRD27 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 324/722 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs1226244031, COSV60131036, COSV60133634; called by muse, mutect2, varscan2
- ANKRD28 | c.2471G>T p.R824I | Missense Mutation (SNP) | VAF 167/311 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101080793; called by muse, mutect2, varscan2
- ANKRD29 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV52426429; called by muse, varscan2
- ANKRD30A | c.548G>T p.R183I (on ENST00000611781; = p.R127I on NM_052997.2) | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV64611285; called by muse, varscan2
- ANKRD40 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as rs763470156, COSV53333125; called by muse, mutect2, varscan2
- ANKRD44 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1337727205, COSV56550318, COSV56563856; called by muse, mutect2, varscan2
- ANKRD55 | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 80/348 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV61949742; called by muse, mutect2, varscan2
- ANKS1A | c.1682A>G p.D561G | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); catalogued as rs749624668; called by muse, mutect2, varscan2
- ANKS6 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs764745147; called by muse, mutect2, varscan2
- ANKZF1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs776602507, COSV55478437; called by muse, mutect2, varscan2
- ANLN | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV56078070; called by muse, mutect2, varscan2
- ANLN | c.2725C>T p.R909* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV56078317; called by muse, mutect2, varscan2
- ANLN | c.3316C>A p.L1106I | Missense Mutation (SNP) | VAF 111/774 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV56079837; called by muse, mutect2, varscan2
- ANO2 | c.2734C>A p.L912I (on ENST00000356134 / NM_001278597.3; = p.L916I on NM_001278596.3) | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV100499651, COSV100499750; called by muse, varscan2
- ANO2 | c.2159C>T p.S720L (on ENST00000356134 / NM_001278597.3; = p.S724L on NM_001278596.3) | Missense Mutation (SNP) | VAF 200/417 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs764183496, COSV59017542; called by muse, mutect2, varscan2
- ANO3 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 54/257 reads (21%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- ANO4 | c.352C>T p.R118* (on ENST00000392977 / NM_001286615.2; = p.R83* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 131/312 reads (42%) | catalogued as COSV54615264; called by muse, mutect2, varscan2
- ANO5 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 68/288 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1554920664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO5 | c.2236-1G>T p.X746_splice | Splice Site (SNP) | VAF 34/199 reads (17%) | catalogued as rs1391540416, COSV61083846; called by muse, mutect2, varscan2
- ANP32A | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs776705409, COSV51189363; called by muse, mutect2, varscan2
- ANPEP | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs145940069, COSV100262726; called by muse, mutect2, varscan2
- ANTXR1 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1269965949; called by muse, varscan2
- ANXA2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100222168; called by muse, mutect2, varscan2
- ANXA5 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396794753, COSV56640132; called by muse, mutect2, varscan2
- AOC1 | c.580T>G p.S194A | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs1488548734, COSV100710858; called by muse, mutect2, varscan2
- AOC1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766897897; called by muse, mutect2, varscan2
- AOC3 | c.17T>C p.I6T | Missense Mutation (SNP) | VAF 171/355 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53828883; called by muse, mutect2, varscan2
- AP002748.5 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs759253107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1B1 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 151/385 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs763283898; called by muse, mutect2, varscan2
- AP1M2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746291058, COSV51566733; called by muse, mutect2, varscan2
- AP2B1 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.563); catalogued as COSV51998271; called by muse, mutect2, varscan2
- AP2M1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1488778255; called by muse, mutect2, varscan2
- AP2M1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 273/509 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490851; called by muse, mutect2, varscan2
- AP3B1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs765852823, COSV54882994; called by muse, mutect2, varscan2
- AP3M1 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.246); catalogued as COSV53009026, COSV53015958; called by muse, mutect2, varscan2
- AP4E1 | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.086); catalogued as COSV99956848; called by muse, mutect2, varscan2
- AP4E1 | c.2953A>G p.T985A | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs200469310; called by muse, mutect2, varscan2
- AP5B1 | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1394981727; called by muse, mutect2, varscan2
- APC | c.274T>C p.S92P | Missense Mutation (SNP) | VAF 129/214 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.083); catalogued as COSV57361114; called by muse, mutect2, varscan2
- APC | c.2717C>A p.S906Y | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV57344220, COSV57391056, COSV57403393; called by muse, mutect2, varscan2
- APCDD1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370464025; called by muse, mutect2, varscan2
- APCDD1L | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as rs765708116; called by muse, mutect2, varscan2
- APLP1 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs764183374; called by muse, mutect2, varscan2
- APMAP | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200046619; called by muse, mutect2, varscan2
- APOA4 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs756971543, COSV100759293, COSV100759300; called by muse, mutect2
- APOB | c.11687C>T p.A3896V | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.026); catalogued as rs759708973, COSV51931713; called by muse, varscan2
- APOB | c.9107C>T p.S3036F | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV51925687; called by muse, mutect2, varscan2
- APOBEC3F | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs369091002; called by muse, varscan2
- APOBEC3H | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as COSV100818863; called by muse, mutect2, varscan2
- APOC3 | c.213A>C p.K71N | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV52635278; called by muse, mutect2, varscan2
- APOH | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs149659675, COSV99235551; called by muse, mutect2, varscan2
- APOL2 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.886); catalogued as rs748565716; called by mutect2, varscan2
- APOL6 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs779047404, COSV68749424; called by muse, mutect2, varscan2
- APOOL | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs776934666, COSV64272260; called by muse, mutect2, varscan2
- APP | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1800557, CM920068, COSV60997688, COSV61003534; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- APP | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs376138420, COSV61006586; called by muse, mutect2, varscan2
- APTX | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs747334007; ClinVar: likely benign; called by muse, mutect2, varscan2
- AQP10 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV61475754; called by muse, varscan2
- AQP10 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1270423632; called by muse, varscan2
- AQP8 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV54844611; called by muse, mutect2, varscan2
- ARAP2 | c.4443G>T p.K1481N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV58285905; called by muse, mutect2, varscan2
- ARAP3 | c.3728G>A p.R1243H | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs748063043; called by muse, mutect2, varscan2
- ARFGAP3 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs756482945, COSV54311590; called by muse, mutect2, varscan2
- ARFGEF1 | c.4042C>T p.R1348C | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370394131; called by muse, mutect2, varscan2
- ARFGEF1 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 135/320 reads (42%) | catalogued as COSV51607584; called by muse, mutect2, varscan2
- ARFGEF1 | c.2395C>T p.R799* | Nonsense Mutation (SNP) | VAF 34/148 reads (23%) | catalogued as rs1563869264, COSV51614726; called by muse, mutect2, varscan2
- ARFGEF1 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as COSV51608984; called by muse, mutect2, varscan2
- ARFGEF3 | c.5599G>A p.A1867T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as rs766044916, COSV52457823; called by mutect2, varscan2
- ARG2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs371149374; called by muse, mutect2, varscan2
- ARHGAP10 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs759498019, COSV60602830; called by muse, mutect2, varscan2
- ARHGAP11A | c.2515C>T p.R839C | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767940461, COSV55705698; called by muse, mutect2, varscan2
- ARHGAP18 | c.1756C>A p.L586I | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as COSV63763224; called by muse, mutect2, varscan2
- ARHGAP20 | c.3338C>A p.S1113Y | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52805929, COSV99503010; called by muse, mutect2, varscan2
- ARHGAP21 | c.5288C>T p.T1763M | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1266129181; called by muse, varscan2
- ARHGAP21 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 73/423 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs771305026, COSV100256084; called by muse, varscan2
- ARHGAP21 | c.4852G>A p.E1618K | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs371210209; called by muse, mutect2, varscan2
- ARHGAP21 | c.1934C>A p.S645Y | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV57605468; called by muse, mutect2, varscan2
- ARHGAP24 | c.704C>T p.A235V (on ENST00000395184 / NM_001025616.3; = p.A142V on NM_031305.3) | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs760970265; called by muse, mutect2, varscan2
- ARHGAP28 | c.1586G>T p.R529L (on ENST00000383472 / NM_001366230.1; = p.R370L on NM_001010000.3) | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs778940127, COSV51649179; called by muse, mutect2, varscan2
- ARHGAP29 | c.3409G>T p.E1137* | Nonsense Mutation (SNP) | VAF 41/223 reads (18%) | catalogued as COSV53110692; called by muse, varscan2
- ARHGAP29 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs770643185, COSV53109092; called by muse, mutect2, varscan2
- ARHGAP30 | c.2996C>T p.A999V (on ENST00000368013 / NM_001025598.2; = p.A788V on NM_181720.3) | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs957301704; called by muse, mutect2, varscan2
- ARHGAP30 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 103/489 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1443757540, COSV63518232; called by muse, mutect2, varscan2
- ARHGAP30 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 149/337 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753681564; called by muse, mutect2, varscan2
- ARHGAP35 | c.3317C>T p.S1106F | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1475854691; called by muse, mutect2, varscan2
- ARHGAP35 | c.4315C>T p.R1439W | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs986522562, COSV68331276; called by muse, varscan2
- ARHGAP36 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 161/578 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as rs1194619100; called by muse, varscan2
- ARHGAP44 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52390291; called by muse, mutect2, varscan2
- ARHGAP44 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs375812578; called by muse, mutect2, varscan2
- ARHGAP5 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs753743151; called by muse, mutect2, varscan2
- ARHGDIB | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs747574555, COSV57456230; called by muse, mutect2, varscan2
- ARHGEF1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs529943853, COSV100528943; called by muse, mutect2, varscan2
- ARHGEF10 | c.1397C>T p.T466M (on ENST00000398564; = p.T441M on NM_014629.4) | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs146529284; called by muse, mutect2, varscan2
- ARHGEF10L | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751901583; called by muse, mutect2, varscan2
- ARHGEF15 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.328); catalogued as rs149554572; called by muse, varscan2
- ARHGEF17 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs1307589484, COSV99735795; called by muse, mutect2, varscan2
- ARHGEF28 | c.3784C>T p.P1262S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs771395365; called by muse, mutect2, varscan2
- ARHGEF37 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61369936; called by muse, varscan2
- ARHGEF37 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 97/171 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs781049357, COSV61368914; called by muse, mutect2, varscan2
- ARHGEF40 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs777087278; called by muse, varscan2
- ARHGEF5 | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs758714011, COSV50218100; called by mutect2, varscan2
- ARHGEF7 | c.1966C>T p.R656W (on ENST00000375741 / NM_001113511.2; = p.R478W on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866152255, COSV54538783, COSV54548582; called by muse, mutect2
- ARID4B | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753915756, COSV51597949, COSV51602687; called by muse, mutect2, varscan2
- ARID5B | c.2606C>A p.S869Y | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.185); catalogued as rs201944744, COSV54415661; called by muse, mutect2, varscan2
- ARIH1 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753701203, COSV65912725; called by muse, mutect2, varscan2
- ARL13A | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 31/124 reads (25%) | catalogued as rs374188162, COSV71448328; called by muse, mutect2, varscan2
- ARL13A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs553228239, COSV65880071; called by muse, mutect2, varscan2
- ARMC1 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52533636; called by muse, varscan2
- ARMC12 | c.445G>A p.E149K (on ENST00000373866 / NM_001286574.2; = p.E176K on NM_145028.5) | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); catalogued as COSV55361484; called by muse, mutect2, varscan2
- ARMC2 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV64551980; called by muse, mutect2, varscan2
- ARMC3 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as rs996580496; called by muse, mutect2, varscan2
- ARMC3 | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV99958855; called by muse, mutect2, varscan2
- ARMC4 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 83/414 reads (20%) | catalogued as COSV99519164; called by muse, mutect2, varscan2
- ARMC6 | c.347G>A p.R116H (on ENST00000392336; = p.R91H on NM_033415.4) | Missense Mutation (SNP) | VAF 121/355 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as rs754786135; called by muse, mutect2, varscan2
- ARMC8 | c.808C>T p.R270W (on ENST00000469044 / NM_001363941.2; = p.R256W on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs1426021184, COSV100627866; called by muse, mutect2, varscan2
- ARMH3 | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV100899024; called by muse, mutect2, varscan2
- ARNTL2 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 69/288 reads (24%) | catalogued as rs55752721; called by muse, mutect2, varscan2
- ARR3 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 36/194 reads (19%) | catalogued as rs1192044232, COSV57204706; called by muse, mutect2, varscan2
- ARRDC5 | c.59C>T p.S20L (on ENST00000381781; = p.S6L on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/299 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs773823469, COSV104432113; called by muse, mutect2, varscan2
- ARSI | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs771311478; called by muse, varscan2
- ARSK | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 68/344 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as rs763396857, COSV66169295; called by muse, varscan2
- ARSK | c.1436C>A p.S479Y | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV66170403; called by muse, mutect2, varscan2
- ART1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs1467007903, COSV51705482; called by muse, mutect2, varscan2
- ASAH2B | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs551101710, COSV51768400; called by muse, mutect2, varscan2
- ASB10 | c.634G>A p.E212K (on ENST00000420175 / NM_001142459.2; = p.E197K on NM_080871.4) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs780800752; called by muse, mutect2, varscan2
- ASB10 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1001220258; called by muse, mutect2, varscan2
- ASB2 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs372274381, COSV100279170; called by muse, mutect2
- ASB3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 86/352 reads (24%) | catalogued as rs1317747370; called by muse, mutect2, varscan2
- ASB5 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768368243; called by muse, varscan2
- ASB5 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV56668979; called by muse, varscan2
- ASCC1 | c.560C>T p.A187V (on ENST00000342444 / NM_001369085.1; = p.A159V on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs778835382; called by muse, mutect2, varscan2
- ASH1L | c.8089G>T p.D2697Y (on ENST00000368346 / NM_001366177.2; = p.D2692Y on NM_018489.3) | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as COSV64206391; called by muse, varscan2
- ASH1L | c.4748C>T p.S1583F | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1307913661; called by muse, varscan2
- ASIC5 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV73332795; called by muse, mutect2
- ASIC5 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751203128; called by muse, mutect2, varscan2
- ASPDH | c.566G>A p.R189Q (on ENST00000389208 / NM_001114598.2; = p.R84Q on NM_001024656.3) | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV65350184; called by muse, mutect2, varscan2
- ASPH | c.562A>G p.M188V | Missense Mutation (SNP) | VAF 202/541 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs750444872, COSV100727662; called by muse, mutect2, varscan2
- ASPHD1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV58097098; called by muse, mutect2, varscan2
- ASPHD2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 192/419 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs779755180, COSV53219738; called by muse, mutect2, varscan2
- ASPM | c.7325G>A p.R2442Q | Missense Mutation (SNP) | VAF 118/278 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745339338, COSV99659686; called by muse, varscan2
- ASPM | c.6034G>T p.E2012* | Nonsense Mutation (SNP) | VAF 62/299 reads (21%) | catalogued as COSV54128893; called by muse, mutect2, varscan2
- ASPM | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs142655430, COSV54127984; called by muse, mutect2, varscan2
- ASPN | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs748965890; called by muse, mutect2, varscan2
- ASTL | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs757814790; called by muse, mutect2, varscan2
- ASTN2 | c.1157G>A p.S386N | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs1198319584, COSV100526596; called by muse, mutect2, varscan2
- ASXL3 | c.4750C>T p.R1584C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs755390840, COSV52462370, COSV99322987; called by muse, mutect2, varscan2
- ATAD1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs1470602790; called by muse, mutect2, varscan2
- ATAD2B | c.3962C>T p.S1321L | Missense Mutation (SNP) | VAF 76/344 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as rs765383233, COSV53196387; called by muse, mutect2, varscan2
- ATAD2B | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs950121871; called by muse, mutect2, varscan2
- ATCAY | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs370499062; called by muse, mutect2, varscan2
- ATF2 | c.744C>T p.L248= | Splice Region (SNP) | VAF 102/187 reads (55%) | catalogued as COSV51368935; called by muse, mutect2, varscan2
- ATF5 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV100351936; called by muse, mutect2
- ATG101 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as rs778694622; called by muse, varscan2
- ATG2B | c.5428G>A p.E1810K | Missense Mutation (SNP) | VAF 122/159 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs759363991, COSV99952224; called by muse, mutect2, varscan2
- ATM | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs141087784, CM014033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.4600G>A p.V1534I | Missense Mutation (SNP) | VAF 70/360 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs745351684; called by muse, mutect2, varscan2
- ATM | c.8650G>T p.E2884* | Nonsense Mutation (SNP) | VAF 76/176 reads (43%) | catalogued as COSV53739484; called by muse, varscan2
- ATP10B | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766661717; called by muse, mutect2, varscan2
- ATP10B | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100514665; called by muse, mutect2, varscan2
- ATP10B | c.1387C>T p.R463* | Nonsense Mutation (SNP) | VAF 133/366 reads (36%) | catalogued as rs200879991; called by muse, mutect2, varscan2
- ATP10D | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs750138858, COSV56704068; called by muse, mutect2, varscan2
- ATP11A | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745652275; called by muse, mutect2, varscan2
- ATP11B | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.251); catalogued as rs769443660, COSV100017797; called by muse, mutect2, varscan2
- ATP11B | c.1580C>A p.S527Y | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60027347; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 30/183 reads (16%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP12A | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs376103804; called by muse, varscan2
- ATP13A1 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV52284065; called by muse, mutect2, varscan2
- ATP13A2 | c.2175G>T p.R725S | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1232321702; called by muse, mutect2, varscan2
- ATP13A3 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs756090170, COSV55467236; called by muse, mutect2, varscan2
- ATP13A5 | c.3486G>T p.K1162N | Missense Mutation (SNP) | VAF 186/362 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99290512; called by muse, mutect2, varscan2
- ATP13A5 | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 36/139 reads (26%) | catalogued as rs753509516, COSV60877842; called by muse, mutect2, varscan2
- ATP13A5 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 65/218 reads (30%) | catalogued as COSV100666040; called by muse, mutect2, varscan2
- ATP1A1 | c.3042C>T p.G1014= | Splice Region (SNP) | VAF 64/248 reads (26%) | catalogued as COSV55190117; called by muse, mutect2, varscan2
- ATP1A3 | c.1057C>T p.R353C (on ENST00000545399 / NM_001256214.2; = p.R340C on NM_152296.5) | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs782018096; called by muse, mutect2, varscan2
- ATP23 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 116/493 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479183882, COSV55685387; called by muse, varscan2
- ATP2A2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV58048028; called by muse, mutect2, varscan2
- ATP2A3 | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.331); catalogued as rs754507656; called by mutect2, varscan2
- ATP2A3 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs1030060199, COSV59226954; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP2B1 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53812601; called by muse, mutect2, varscan2
- ATP2B3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 136/230 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781989417; called by muse, mutect2, varscan2
- ATP2B4 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1386030190; called by muse, varscan2
- ATP2C1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146989; called by muse, mutect2, varscan2
- ATP4A | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs764421480, COSV52865125; called by muse, mutect2, varscan2
- ATP5IF1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs374584642; called by muse, mutect2, varscan2
- ATP5PD | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as rs377594522, COSV56902613; called by muse, mutect2, varscan2
- ATP6V0D1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.989); catalogued as rs775286082; called by muse, mutect2, varscan2
- ATP6V1A | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs758392307; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 138/339 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs751041922; called by muse, mutect2, varscan2
- ATP6V1C1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as rs372629798, COSV67778709; called by muse, varscan2
- ATP6V1G2 | c.271A>G p.N91D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1429660183; called by muse, mutect2, varscan2
- ATP7B | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1305827368; called by muse, mutect2, varscan2
- ATP8A1 | c.3181G>A p.A1061T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs200291526; called by mutect2, varscan2
- ATP8B1 | c.1032C>T p.I344= | Splice Region (SNP) | VAF 13/35 reads (37%) | catalogued as rs1231339266; called by muse, mutect2
- ATP8B2 | c.1939C>T p.R647* (on ENST00000672630; = p.R614* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 41/107 reads (38%) | catalogued as rs1263937344, COSV100527831; called by muse, mutect2, varscan2
- ATP8B3 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs755138497; called by muse, varscan2
- ATP8B4 | c.3157C>T p.P1053S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV52711968; called by muse, mutect2, varscan2
- ATP9A | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 64/147 reads (44%) | catalogued as COSV100124947; called by muse, mutect2, varscan2
- ATR | c.7471G>A p.V2491I | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs556313656, COSV100638843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATR | c.4235G>A p.R1412Q | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.63); catalogued as rs371292374, COSV63384323; called by muse, mutect2, varscan2
- ATR | c.4102C>T p.R1368* | Nonsense Mutation (SNP) | VAF 145/313 reads (46%) | catalogued as rs1194388677, COSV63385619; called by muse, mutect2, varscan2
- ATR | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.106); catalogued as rs532495501, COSV63383731; called by muse, mutect2, varscan2
- ATRN | c.2518C>T p.R840* | Nonsense Mutation (SNP) | VAF 70/149 reads (47%) | catalogued as rs1368168673; called by muse, mutect2, varscan2
- ATRNL1 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV61817900; called by muse, mutect2, varscan2
- ATRX | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as rs781811015, COSV64873205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.2519G>T p.R840I | Missense Mutation (SNP) | VAF 170/614 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as rs191682105, COSV64871123, COSV64876976; called by muse, mutect2, varscan2
- ATRX | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 244/455 reads (54%) | catalogued as rs1311466929, COSV64873935; called by muse, mutect2, varscan2
- ATXN7 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55750731; called by muse, mutect2, varscan2
- AUTS2 | c.2693C>T p.S898L | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.356); catalogued as rs534033649, COSV61412956; called by muse, mutect2, varscan2
- AUTS2 | c.2785G>A p.A929T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1340261250; called by muse, mutect2
- AVL9 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs555473914; called by muse, varscan2
- AXDND1 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV62648508; called by muse, mutect2, varscan2
- AXL | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 71/355 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs201596308, COSV56571583; called by muse, mutect2, varscan2
- AXL | c.1496G>A p.R499H (on ENST00000301178 / NM_021913.5; = p.R490H on NM_001699.6) | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs200850031; called by muse, mutect2, varscan2
- AZU1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145363133; called by muse, mutect2, varscan2
- B2M | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs148494241, COSV62562854; called by muse, mutect2, varscan2
- B3GALNT2 | c.1028C>T p.T343I | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV64003621; called by muse, mutect2, varscan2
- B3GAT2 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445262803, COSV57771511; called by muse, mutect2, varscan2
- B3GNT4 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 301/692 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs942692043, COSV57336917; called by muse, mutect2, varscan2
- B3GNT7 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs765053112, COSV55007155; called by muse, varscan2
- B3GNT7 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs899688441, COSV55006371; called by muse, varscan2
- B4GALNT1 | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57542781; called by muse, mutect2, varscan2
- B4GALT6 | c.795T>G p.F265L | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV52703457; called by muse, mutect2, varscan2
- B4GAT1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1450752829; called by muse, mutect2
- BABAM1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs1230353465, COSV100845734; called by muse, mutect2, varscan2
- BACE2 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 244/588 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751699716, COSV57738664; called by muse, varscan2
- BACH1 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs140484641; called by muse, mutect2, varscan2
- BAG4 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs1347629668; called by muse, mutect2, varscan2
- BAG6 | c.3340G>A p.A1114T (on ENST00000676571; = p.A1067T on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as rs774730487, COSV99277998; called by muse, mutect2, varscan2
- BAG6 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771400122, COSV52992058; called by muse, mutect2, varscan2
- BANF1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 22/144 reads (15%) | catalogued as rs1220650310, COSV56463510; called by muse, mutect2, varscan2
- BAP1 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 127/547 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV56232414; called by muse, mutect2, varscan2
- BAZ1B | c.1718G>A p.R573K | Missense Mutation (SNP) | VAF 132/619 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV59992645; called by muse, mutect2, varscan2
- BAZ2A | c.4960G>A p.A1654T | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1463531906; called by muse, mutect2, varscan2
- BAZ2B | c.4141C>T p.R1381C | Missense Mutation (SNP) | VAF 115/185 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1381457323, COSV58611135; called by muse, varscan2
- BAZ2B | c.4117C>T p.R1373C | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771663406; called by muse, varscan2
- BAZ2B | c.2375G>T p.R792I | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV58599170; called by muse, mutect2, varscan2
- BBS10 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs553291328, CM111656, COSV99674826; called by muse, mutect2, varscan2
- BBS9 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs899716022, COSV54157337; called by muse, mutect2, varscan2
- BBS9 | c.1799G>A p.R600H (on ENST00000242067 / NM_001348036.1; = p.R560H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749018243, COSV54189065; called by muse, mutect2, varscan2
- BBX | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 53/134 reads (40%) | catalogued as COSV57887965; called by muse, mutect2, varscan2
- BCAM | c.507C>T p.I169= | Splice Region (SNP) | VAF 62/153 reads (41%) | catalogued as rs1014808418, COSV54305037; called by muse, mutect2, varscan2
- BCAT1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as rs201533470, COSV53918168; called by muse, mutect2, varscan2
- BCKDHB | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 93/149 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs933828560, COSV57511238; called by muse, mutect2, varscan2
- BCKDK | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as rs1179017145; called by muse, mutect2, varscan2
- BCL2L10 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.164); catalogued as COSV53064610, COSV53064951; called by muse, mutect2, varscan2
- BCL2L13 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as rs781280648; called by muse, mutect2, varscan2
- BCL2L14 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs762092613; called by muse, varscan2
- BCL6B | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 87/207 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763059247, COSV53426235; called by muse, mutect2, varscan2
- BCLAF3 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 302/514 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs772915174, COSV100503249; called by muse, mutect2, varscan2
- BCO1 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs746137348; called by muse, mutect2, varscan2
- BCO2 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV63062529; called by muse, mutect2, varscan2
- BDKRB2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs992787256, COSV60013501; called by muse, mutect2, varscan2
- BDKRB2 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.22); PolyPhen benign (0.233); catalogued as rs146650268; called by muse, mutect2, varscan2
- BDP1 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.147); catalogued as rs756417651, COSV62431133; called by muse, varscan2
- BDP1 | c.5683G>A p.E1895K | Missense Mutation (SNP) | VAF 111/276 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1226557808; called by muse, mutect2, varscan2
- BDP1 | c.6979G>A p.E2327K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs1561780075; called by muse, mutect2, varscan2
- BEST1 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); catalogued as COSV99861280; called by muse, varscan2
- BEST4 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs370479919; called by muse, mutect2, varscan2
- BFSP1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746995142, COSV64899273; called by muse, varscan2
- BFSP1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as rs772228624; called by muse, varscan2
- BHMT | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs772421189, COSV57155721; called by muse, mutect2, varscan2
- BICC1 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54067698; called by muse, mutect2, varscan2
- BICC1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | catalogued as rs201753164, COSV65856907; called by muse, mutect2, varscan2
- BICD1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs1264580521, COSV99861797; called by muse, mutect2, varscan2
- BICRAL | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 137/223 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.208); catalogued as rs200962323; called by muse, mutect2, varscan2
- BIK | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 153/320 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs766525617; called by muse, varscan2
- BIN1 | c.827G>A p.S276N (on ENST00000316724 / NM_001320642.1; = p.S245N on NM_004305.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs1327705608; called by muse, mutect2, varscan2
- BIRC2 | c.1762C>A p.H588N | Missense Mutation (SNP) | VAF 110/226 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57162832; called by muse, mutect2, varscan2
- BIRC6 | c.4541G>A p.G1514D | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); catalogued as COSV70203674; called by muse, mutect2, varscan2
- BIRC6 | c.12717G>T p.L4239F | Missense Mutation (SNP) | VAF 133/229 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70207878; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99958434; called by muse, varscan2
- BIVM-ERCC5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs776035108; called by muse, varscan2
- BLK | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs775132094; called by muse, mutect2, varscan2
- BLM | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.204); catalogued as COSV61928139; called by muse, mutect2, varscan2
- BLM | c.1910G>T p.R637I | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV61921462; called by muse, mutect2, varscan2
- BLM | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs780514723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLOC1S5 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs376789498; called by muse, mutect2, varscan2
- BLOC1S5 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs775046437; called by muse, mutect2, varscan2
- BMP10 | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99770239; called by muse, mutect2, varscan2
- BMP5 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63700843, COSV63703329; called by muse, mutect2, varscan2
- BMP6 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.038); catalogued as rs1308444167, COSV99306396; called by muse, mutect2, varscan2
- BMP8B | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs775864111, COSV59593603; called by muse, varscan2
- BMPER | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 90/189 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs771286519, COSV51822299; called by muse, mutect2, varscan2
- BMPR1A | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV100776701; called by muse, mutect2, varscan2
- BMPR2 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65811986; called by muse, mutect2, varscan2
- BMS1 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 128/268 reads (48%) | catalogued as rs1222409433, COSV65735395; called by muse, mutect2, varscan2
- BMS1 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 92/467 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65734541; called by muse, mutect2, varscan2
- BMS1 | c.2641C>T p.R881* | Nonsense Mutation (SNP) | VAF 57/245 reads (23%) | catalogued as rs1457713813, COSV65732842; called by muse, mutect2, varscan2
- BMX | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 113/413 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1375536026; called by muse, mutect2, varscan2
- BNC1 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 92/218 reads (42%) | catalogued as COSV61756465, COSV61757343; called by muse, varscan2
- BNIP1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 180/278 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776652848, COSV51571239; called by muse, varscan2
- BOC | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.362); catalogued as rs751976756, COSV56349674; called by muse, mutect2, varscan2
- BOC | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as rs754897087; called by muse, varscan2
- BOC | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs746607862; called by muse, mutect2, varscan2
- BORA | c.911C>T p.S304L (on ENST00000613797; = p.S229L on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1330509036; called by muse, mutect2, varscan2
- BORCS5 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 82/367 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1473274204, COSV100055795; called by muse, mutect2, varscan2
- BPIFB3 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs950976642, COSV64956996, COSV64957549; called by muse, mutect2, varscan2
- BPIFB6 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 71/393 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs766503313, COSV62754771; called by muse, mutect2, varscan2
- BPNT2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV99389092; called by muse, mutect2, varscan2
- BRAF | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 52/257 reads (20%) | catalogued as COSV56416185; called by muse, mutect2, varscan2
- BRCA2 | c.794-1G>T p.X265_splice | Splice Site (SNP) | VAF 68/132 reads (52%) | catalogued as COSV66452482; called by muse, mutect2, varscan2
- BRCA2 | c.3155C>T p.A1052V | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1060502453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.5385A>C p.K1795N | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV101204250; called by muse, mutect2, varscan2
- BRCA2 | c.8524C>T p.R2842C | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359104, COSV66450665, COSV66453321; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.3841C>T p.R1281W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs754054879; called by muse, varscan2
- BRD4 | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs202165230, COSV54589213; called by mutect2, varscan2
- BRD4 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs779993356; called by muse, mutect2, varscan2
- BRINP2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771272662, COSV100838021, COSV64180814; called by muse, mutect2, varscan2
- BRINP2 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 99/210 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.059); catalogued as rs137996038; called by muse, mutect2, varscan2
- BRINP3 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs765103774, COSV66523080; called by muse, mutect2, varscan2
- BRPF3 | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs192361205; called by muse, mutect2, varscan2
- BRSK1 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 65/163 reads (40%) | catalogued as COSV58665011; called by muse, mutect2, varscan2
- BRSK2 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1043745449, COSV57541144; called by muse, mutect2, varscan2
- BRWD1 | c.2618G>A p.G873D | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370519269, COSV60902278; called by muse, mutect2, varscan2
- BRWD1 | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406282052, COSV60899182; called by muse, mutect2, varscan2
- BSX | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1012698643; called by muse, mutect2, varscan2
- BTAF1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs950040547, COSV56431992; called by muse, mutect2, varscan2
- BTBD16 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs202210822, COSV53260423; called by muse, mutect2, varscan2
- BTK | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 95/385 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as CM1413235; called by muse, varscan2
- BTN1A1 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 127/441 reads (29%) | catalogued as rs755009512, COSV55067679; called by muse, mutect2, varscan2
- BTN2A2 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.665); catalogued as rs577086730, COSV61858459; called by muse, mutect2, varscan2
- BZW2 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV51755684; called by muse, mutect2
- C10orf120 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577934787, COSV61492459; called by muse, mutect2, varscan2
- C10orf71 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60505727; called by muse, mutect2, varscan2
- C10orf71 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs371353601; called by muse, mutect2, varscan2
- C10orf71 | c.1625T>C p.V542A | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.121); catalogued as rs1331359577, COSV60509659; called by muse, mutect2, varscan2
- C10orf90 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1333506506, COSV52950556; called by muse, mutect2, varscan2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by muse, mutect2, varscan2
- C12orf50 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs1268285762; called by muse, mutect2, varscan2
- C14orf93 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); catalogued as rs529811646; called by muse, mutect2, varscan2
- C16orf70 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV54627583; called by muse, mutect2, varscan2
- C18orf54 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 94/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs536394320, COSV55618522; called by muse, mutect2, varscan2
- C18orf54 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as COSV100266611; called by muse, mutect2, varscan2
- C19orf18 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs775940159; called by muse, varscan2
- C1QB | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV59244955; called by muse, mutect2, varscan2
- C1QTNF1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1232814957, COSV59261780; called by muse, mutect2, varscan2
- C1QTNF9 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779386798, COSV59656776; called by muse, mutect2, varscan2
- C1QTNF9B | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1463638854, COSV65943913; called by muse, mutect2, varscan2
- C1R | c.2041C>T p.R681C (on ENST00000536053 / NM_001354346.2; = p.R667C on NM_001733.7) | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs763888790, COSV73383063; called by muse, mutect2, varscan2
- C1orf100 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 68/184 reads (37%) | catalogued as COSV57374076; called by muse, mutect2, varscan2
- C1orf116 | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs781554923; called by muse, mutect2, varscan2
- C1orf116 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV63944558; called by muse, mutect2, varscan2
- C1orf162 | c.402C>A p.H134Q | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV59058982; called by muse, mutect2, varscan2
- C1orf198 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 235/477 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs753381372; called by muse, mutect2, varscan2
- C1orf210 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as rs1268460954; called by muse, mutect2, varscan2
- C1orf43 | c.194G>A p.R65Q (on ENST00000368521 / NM_001297718.2; = p.R31Q on NM_015449.4) | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs577642353; called by muse, varscan2
- C1orf87 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs757474276, COSV100967242; called by muse, mutect2, varscan2
- C1orf87 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.152); catalogued as COSV100967041, COSV100967291; called by muse, mutect2, varscan2
- C1orf94 | c.631C>A p.L211M (on ENST00000488417 / NM_001134734.2; = p.L21M on NM_032884.5) | Missense Mutation (SNP) | VAF 110/199 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV64914439; called by muse, mutect2, varscan2
- C1orf94 | c.887C>T p.P296L (on ENST00000488417 / NM_001134734.2; = p.P106L on NM_032884.5) | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1331323390; called by muse, mutect2, varscan2
- C1orf94 | c.1235G>A p.R412Q (on ENST00000488417 / NM_001134734.2; = p.R222Q on NM_032884.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.845); catalogued as rs374427865, COSV64913415; called by mutect2, varscan2
- C2 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 128/202 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147553278; called by muse, mutect2, varscan2
- C20orf194 | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs978405040; called by muse, mutect2, varscan2
- C2CD2L | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 168/387 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1376923865, COSV60884019; called by muse, mutect2, varscan2
- C2CD5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1358127069, COSV61724153; called by muse, varscan2
- C2CD5 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 89/202 reads (44%) | catalogued as rs760237312, COSV61728011; called by muse, varscan2
- C2CD6 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 105/200 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs763197632; called by muse, mutect2, varscan2
- C2orf16 | c.3563T>C p.V1188A | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs758200083; called by muse, mutect2, varscan2
- C2orf69 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs762047776, COSV60666313; called by muse, mutect2, varscan2
- C2orf78 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as rs760458331; called by muse, mutect2, varscan2
- C2orf78 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375008239; called by muse, mutect2, varscan2
- C3 | c.4111C>T p.P1371S | Missense Mutation (SNP) | VAF 138/368 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1369718625; called by muse, mutect2, varscan2
- C3AR1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs751672588, COSV50821123, COSV99368180; called by muse, mutect2, varscan2
- C3orf22 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs202039278, COSV100559560; called by muse, mutect2, varscan2
- C3orf38 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV59628936; called by muse, varscan2
- C5orf22 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs756366812, COSV57599240; called by muse, mutect2, varscan2
- C6orf120 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs772042079; called by muse, mutect2, varscan2
- C7 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs755950201, COSV100495266, COSV57482404; called by muse, varscan2
- C7orf57 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369752964; called by muse, mutect2, varscan2
- C9orf131 | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 159/393 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs995176967, COSV56612844; called by muse, mutect2, varscan2
- CA1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs769195145; called by muse, mutect2, varscan2
- CA12 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs547471188; called by muse, mutect2, varscan2
- CA5B | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 220/365 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1210366257; called by muse, mutect2, varscan2
- CABIN1 | c.3587G>A p.R1196H | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs752877361, COSV54081371; called by muse, mutect2, varscan2
- CABIN1 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.981); catalogued as rs772479837; called by mutect2, varscan2
- CABP1 | c.802G>A p.E268K (on ENST00000316803 / NM_001033677.1; = p.E65K on NM_004276.5) | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1328676871, COSV56458203; called by muse, mutect2, varscan2
- CABP4 | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1365576970; called by muse, mutect2, varscan2
- CACHD1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs149564819; called by muse, mutect2, varscan2
- CACNA1B | c.4336G>A p.A1446T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs200865012; called by muse, mutect2, varscan2
- CACNA1D | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs35057005; called by muse, mutect2, varscan2
- CACNA1D | c.1537C>T p.R513C (on ENST00000350061 / NM_001128840.3; = p.R533C on NM_000720.4) | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751711138; called by muse, mutect2, varscan2
- CACNA1E | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs370964593; called by muse, mutect2, varscan2
- CACNA1E | c.3965C>T p.S1322F | Missense Mutation (SNP) | VAF 172/426 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62407041; called by muse, mutect2, varscan2
- CACNA1E | c.5101G>A p.V1701M | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs762078001, COSV62389873; called by muse, mutect2, varscan2
- CACNA1F | c.5263C>T p.R1755W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59906203; called by muse, mutect2, varscan2
- CACNA1F | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | catalogued as rs782074040, CM055909, COSV100545278; called by muse, varscan2
- CACNA1F | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs782740156, COSV59903555; called by muse, mutect2
- CACNA1H | c.4141G>A p.V1381M | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372514242; called by muse, varscan2
- CACNA1H | c.4509G>T p.K1503N | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100671328; called by muse, mutect2, varscan2
- CACNA1H | c.5162G>A p.R1721H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747789914; ClinVar: uncertain significance; called by mutect2, varscan2
- CACNA1I | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 104/477 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs776970877; called by muse, varscan2
- CACNA1I | c.5710G>A p.E1904K | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as rs570266296; called by muse, mutect2, varscan2
- CACNA2D1 | c.2750G>A p.R917H (on ENST00000356253 / NM_001366867.1; = p.R905H on NM_000722.4) | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1013862654, COSV62371881, COSV62386058; called by muse, mutect2, varscan2
- CACNA2D1 | c.2395G>T p.E799* (on ENST00000356253 / NM_001366867.1; = p.E787* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 131/343 reads (38%) | catalogued as rs1554332743, COSV100666722, COSV62392774; called by muse, mutect2, varscan2
- CACNA2D1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as rs373911809; called by muse, mutect2, varscan2
- CACNB2 | c.1976G>A p.R659H (on ENST00000324631 / NM_201596.3; = p.R604H on NM_000724.4) | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs780134367, COSV99993498; called by muse, mutect2, varscan2
- CACNG1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs918445063, COSV56826836; called by muse, mutect2, varscan2
- CACNG7 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV55813346, COSV55816386; called by muse, mutect2, varscan2
- CADM1 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 93/396 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.063); catalogued as rs777959081, COSV59018939, COSV59020194; called by muse, mutect2, varscan2
- CADPS2 | c.1028C>A p.S343Y | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV57362291, COSV57364052; called by muse, mutect2, varscan2
- CALCRL | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201789608, COSV66473826; called by muse, mutect2, varscan2
- CALHM2 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1239885906; called by muse, mutect2, varscan2
- CALN1 | c.82G>A p.E28K (on ENST00000329008 / NM_001017440.3; = p.E70K on NM_031468.4) | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs969416503, COSV61118054; called by muse, mutect2, varscan2
- CALR3 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54168349; called by muse, mutect2, varscan2
- CAMK1 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV56538510; called by muse, mutect2, varscan2
- CAMK1D | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs148446769; called by muse, mutect2, varscan2
- CAMKMT | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as rs140332014; called by muse, mutect2, varscan2
- CAMLG | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); catalogued as COSV51804251; called by muse, mutect2, varscan2
- CAMSAP1 | c.2285G>A p.S762N | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs149066179; called by muse, mutect2, varscan2
- CAMSAP2 | c.1916C>T p.S639L (on ENST00000236925 / NM_001297707.2; = p.S628L on NM_203459.3) | Missense Mutation (SNP) | VAF 160/333 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs375728037; called by muse, mutect2, varscan2
- CAND1 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.432); catalogued as rs755694974, COSV101598255; called by muse, varscan2
- CAND2 | c.1648C>T p.R550W (on ENST00000456430 / NM_001162499.2; = p.R457W on NM_012298.3) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs753838369, COSV55986898; called by muse, mutect2, varscan2
- CAPN1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs534196812; called by muse, varscan2
- CAPN11 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760085717, COSV67237080; called by muse, mutect2, varscan2
- CAPN2 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1211814217; called by muse, mutect2, varscan2
- CAPN6 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs1433800777; called by muse, mutect2, varscan2
- CAPN6 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460207541, COSV60696090; called by muse, mutect2, varscan2
14,468 further variants in this file (10,524 protein-altering or splice-affecting, 3,596 silent, 348 other) are not listed here.
